Somatic mutation profile of tumor specimen MMRF_1061_3_BM_CD138pos (aliquot MMRF_1061_3_BM_CD138pos_T1_KHS5U_L13311) from MMRF case MMRF_1061, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.3 years (25,691 days).
Specimen MMRF_1061_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9202be26-f72f-4de6-af83-e25b075a2e5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1061_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1061_1_PB_Whole_C1_KHS5U_L13433; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f37dbe65-dae1-47a2-84fb-cfef755ddc58

The open-access MAF lists 158 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, 3'UTR 35, Silent 20, Intron 13, Nonsense Mutation 4, Splice Site 4, 3'Flank 3, 5'Flank 3, 5'UTR 2, Frame Shift Del 2, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 60/83 reads (72%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMC8 | c.1126C>T p.R376W (on ENST00000469044 / NM_001363941.2; = p.R362W on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1450402393, COSV100627688, COSV61769891; called by muse, mutect2, varscan2
- BCLAF3 | c.426C>A p.D142E | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV61415396; called by muse, mutect2, varscan2
- CAMTA1 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs966383954, COSV100345986; called by muse, mutect2, varscan2
- CDKN2AIP | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56627768; called by muse, mutect2, varscan2
- CHD2 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 35/66 reads (53%) | catalogued as CD129351; called by muse, mutect2, varscan2
- DLGAP2 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1273654798; called by muse, mutect2, varscan2
- DUSP9 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV61437963; called by muse, mutect2, varscan2
- EHBP1L1 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1204665661; called by muse, mutect2, varscan2
- IGLV2-8 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs762944733; called by muse, varscan2
- IPO11 | c.1928C>G p.P643R | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs373372383; called by muse, mutect2, varscan2
- ITGAM | c.1736C>T p.P579L (on ENST00000648685 / NM_001145808.2; = p.P578L on NM_000632.4) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54938574; called by muse, mutect2, varscan2
- LRRC42 | c.899A>C p.N300T | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.115); catalogued as COSV59961675; called by muse, mutect2, varscan2
- LTBP4 | c.2880C>T p.L960= (on ENST00000308370 / NM_001042544.1; = p.L923= on NM_003573.2) | Splice Region (SNP) | VAF 19/43 reads (44%) | catalogued as COSV52577487; called by muse, mutect2, varscan2
- MAP1B | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.411); catalogued as COSV57102960, COSV57104343; called by muse, mutect2, varscan2
- NODAL | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770958126, COSV54661052; called by muse, mutect2, varscan2
- OR10G4 | c.682C>A p.R228S | Missense Mutation (SNP) | VAF 99/219 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV57979339; called by muse, mutect2, varscan2
- OR4N2 | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750788192, COSV60053250; called by muse, mutect2, varscan2
- PRB4 | c.379G>T p.G127* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV54398134; called by muse, varscan2
- RASGEF1C | c.435C>A p.D145E | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV63184275; called by muse, mutect2, varscan2
- RHBDL3 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as rs772520969; called by muse, mutect2, varscan2
- SIGLEC10 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.168); catalogued as rs762968568; called by muse, mutect2, varscan2
- SOWAHC | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs758294989; called by muse, mutect2, varscan2
- SPON1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1554907633; called by muse, mutect2, varscan2
- ST3GAL2 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | PolyPhen possibly damaging (0.565); catalogued as rs573917099, COSV61597261; called by muse, mutect2, varscan2
- TBKBP1 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV64654679; called by muse, mutect2, varscan2
- TTBK1 | c.2744G>A p.G915D | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.18); catalogued as rs757208521, COSV52491899; called by muse, mutect2, varscan2
- WDHD1 | c.3190G>A p.V1064M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as rs1476181672; called by muse, mutect2, varscan2
- ZNF317 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs1286154379; called by muse, mutect2, varscan2
- AFDN | c.1592A>G p.E531G | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AGPAT4 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ALDH1L2 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ALK | c.2546dup p.Y849* | Nonsense Mutation (INS) | VAF 55/156 reads (35%) | called by mutect2, pindel, varscan2
- AP1G2 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ARHGAP39 | c.1653G>T p.E551D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- BEND2 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCSER1 | c.1128T>G p.N376K | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD19 | c.1619G>C p.G540A (on ENST00000324662 / NM_001178098.2; = p.G539A on NM_001770.6) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CENPJ | c.1757A>G p.D586G | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CEP120 | c.613T>G p.L205V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DAPK1 | c.1919C>T p.T640I | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAAF4 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.3255_3256del p.K1087Nfs*2 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | called by pindel, varscan2
- EEF2 | c.118_122delinsTCAC p.V40Sfs*47 | Frame Shift Del (DEL) | VAF 68/206 reads (33%) | called by pindel, varscan2*
- EPS8L3 | c.1187A>G p.E396G | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM120AOS | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FGD1 | c.2254C>T p.H752Y | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- FGF14 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 70/210 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- GPR158 | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 89/233 reads (38%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- H3C13 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- HCFC1 | c.5396C>T p.P1799L | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV2-11 | c.198dup p.L67Tfs*5 | Frame Shift Ins (INS) | VAF 11/70 reads (16%) | called by pindel, varscan2
- KIAA1109 | c.8678A>G p.K2893R | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LRIT1 | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCEE | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MDN1 | c.6355G>C p.E2119Q | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MMP7 | c.613+1G>A p.X205_splice | Splice Site (SNP) | VAF 37/79 reads (47%) | called by muse, mutect2, varscan2
- MYOM1 | c.3122C>G p.P1041R | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYOM1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 113/350 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- NELL2 | c.1890T>A p.C630* | Nonsense Mutation (SNP) | VAF 64/188 reads (34%) | called by muse, mutect2, varscan2
- NF1 | c.7882A>G p.K2628E (on ENST00000358273 / NM_001042492.3; = p.K2607E on NM_000267.3) | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PATL2 | c.1037T>G p.L346* | Nonsense Mutation (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- PDAP1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCB3 | c.1992C>G p.F664L | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPARGC1A | c.1121A>C p.K374T | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- PPOX | c.1168C>A p.Q390K | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- RB1CC1 | c.251C>A p.P84Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- RTN2 | c.80-1G>A p.X27_splice | Splice Site (SNP) | VAF 79/160 reads (49%) | called by muse, mutect2, varscan2
- SAMD9 | c.508A>T p.S170C | Missense Mutation (SNP) | VAF 111/255 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SDS | c.152G>C p.R51T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC24C | c.1261G>T p.G421C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1B | c.5263A>G p.I1755V | Missense Mutation (SNP) | VAF 87/214 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SNRPD3 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SNTG2 | c.803G>T p.W268L | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPEG | c.2706-1G>T p.X902_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- STARD9 | c.8684C>T p.S2895F | Missense Mutation (SNP) | VAF 66/128 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STARD9 | c.11146G>A p.D3716N | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRIM77 | c.874G>C p.D292H | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- TRPC1 | c.1561T>C p.S521P (on ENST00000476941 / NM_001251845.2; = p.S487P on NM_003304.4) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, varscan2
- UBL4A | c.474G>T p.*158Yext*19 | Nonstop Mutation (SNP) | VAF 108/260 reads (42%) | called by muse, mutect2, varscan2
- XIRP1 | c.584T>G p.F195C | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF671 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AGO1 | c.1062G>A p.L354= | Silent (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- ATP10A | c.3060C>T p.S1020= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs1220922249, COSV100790675; called by muse, mutect2, varscan2
- ATP11A | c.1899G>T p.V633= | Silent (SNP) | VAF 61/177 reads (34%) | catalogued as rs1389518339; called by muse, mutect2, varscan2
- EOMES | c.765G>C p.L255= | Silent (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- GABRG1 | c.30C>A p.S10= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV54950033, COSV54954460; called by muse, mutect2, varscan2
- GEMIN2 | c.696A>G p.S232= | Silent (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- IGLV2-11 | c.51C>T p.S17= | Silent (SNP) | VAF 29/226 reads (13%) | catalogued as rs560847585; called by muse, mutect2, varscan2
- IGLV2-11 | c.135C>T p.S45= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as rs372058556; called by muse, varscan2
- JMJD1C | c.3474T>G p.G1158= | Silent (SNP) | VAF 91/253 reads (36%) | called by muse, mutect2, varscan2
- KIFAP3 | c.1251A>G p.K417= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs1319169074; called by muse, mutect2, varscan2
- KIR3DL3 | c.351C>G p.V117= | Silent (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- KMT2D | c.15051C>T p.G5017= | Silent (SNP) | VAF 64/183 reads (35%) | catalogued as rs1242731561; called by muse, mutect2, varscan2
- LIN37 | c.330C>T p.S110= | Silent (SNP) | VAF 84/207 reads (41%) | catalogued as rs367706790; called by muse, mutect2, varscan2
- MYH7 | c.1878G>C p.G626= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as COSV62517427; called by muse, mutect2, varscan2
- PLPPR4 | c.2196C>A p.G732= | Silent (SNP) | VAF 147/342 reads (43%) | called by muse, mutect2, varscan2
- RBM15B | c.1185G>A p.V395= | Silent (SNP) | VAF 134/321 reads (42%) | called by muse, mutect2, varscan2
- SEMA5B | c.993G>C p.L331= | Silent (SNP) | VAF 10/240 reads (4%) | called by muse, mutect2
- SLC7A8 | c.561A>G p.Q187= | Silent (SNP) | VAF 118/302 reads (39%) | catalogued as COSV57553626; called by muse, mutect2, varscan2
- TBC1D10B | c.2364C>T p.P788= | Silent (SNP) | VAF 89/219 reads (41%) | called by muse, mutect2, varscan2
- UGT1A3 | c.735G>C p.V245= | Silent (SNP) | VAF 75/223 reads (34%) | catalogued as rs760591415; called by muse, mutect2, varscan2
- AADAT | c.67+311G>C | Intron (SNP) | VAF 114/328 reads (35%) | called by muse, mutect2, varscan2
- AHI1 | chr6:135497965 C>T | 5'Flank (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826238 C>A | 3'Flank (SNP) | VAF 110/256 reads (43%) | called by muse, mutect2, varscan2
- ANAPC5 | c.1033-147C>A | Intron (SNP) | VAF 57/161 reads (35%) | called by muse, mutect2, varscan2
- ANO3 | c.*53C>G | 3'UTR (SNP) | VAF 210/626 reads (34%) | called by muse, mutect2, varscan2
- BBS7 | c.601+50G>C | Intron (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2
- BCL2 | c.-599C>T | 5'UTR (SNP) | VAF 76/172 reads (44%) | called by muse, mutect2, varscan2
- BPNT2 | c.*2809C>A | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- C6orf120 | c.*411A>T | 3'UTR (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- CD47 | c.*742A>G | 3'UTR (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- CHRDL1 | c.*251G>T | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- EPYC | c.*439G>A | 3'UTR (SNP) | VAF 25/79 reads (32%) | catalogued as rs578039046; called by muse, mutect2, varscan2
- FAM53C | c.-21A>C | 5'UTR (SNP) | VAF 107/362 reads (30%) | called by muse, mutect2, varscan2
- FBXO2 | chr1:11648145 C>T | 3'Flank (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2, varscan2
- GATAD1 | c.*1128C>G | 3'UTR (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- GRIN2A | c.*1477T>C | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- IRS2 | c.*665A>G | 3'UTR (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- KRTAP5-3 | c.*100C>A | 3'UTR (SNP) | VAF 83/258 reads (32%) | called by muse, mutect2
- LIN28A | c.*165T>G | 3'UTR (SNP) | VAF 93/213 reads (44%) | called by muse, mutect2, varscan2
- LSM11 | c.*4221T>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- MSANTD4 | c.*15C>G | 3'UTR (SNP) | VAF 171/413 reads (41%) | called by muse, mutect2, varscan2
- MUTYH | c.36+1948G>T | Intron (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- NTM | c.*471G>C | 3'UTR (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- OR51L1 | c.*8C>A | 3'UTR (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- OXSM | chr3:25789866 C>G | 5'Flank (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- PDCD10 | c.150+106G>T | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- PPM1B | c.1135-293T>C | Intron (SNP) | VAF 99/228 reads (43%) | called by muse, mutect2, varscan2
- PRRG1 | c.*3602A>G | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.*787T>A | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- RAB22A | c.*7199_*7200dup | 3'UTR (INS) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- RAD1 | chr5:34907604 T>G | 3'Flank (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- RASAL2 | c.*2519T>G | 3'UTR (SNP) | VAF 26/61 reads (43%) | catalogued as rs1558022408; called by muse, mutect2, varscan2
- RASL10B | c.*1080C>T | 3'UTR (SNP) | VAF 76/193 reads (39%) | called by muse, mutect2, varscan2
- RBM15B | c.*2324T>A | 3'UTR (SNP) | VAF 82/221 reads (37%) | called by muse, mutect2, varscan2
- RCAN2 | c.*2234G>A | 3'UTR (SNP) | VAF 35/85 reads (41%) | called by muse, mutect2, varscan2
- RFX3 | c.*4711A>C | 3'UTR (SNP) | VAF 39/93 reads (42%) | called by muse, mutect2, varscan2
- RMND5A | c.*1470A>G | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- RNF217 | c.*7564T>A | 3'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as rs1263998280; called by muse, mutect2, varscan2
- SAMD4A | c.*918G>A | 3'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- SBF2 | c.*826A>G | 3'UTR (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
- SEC16A | c.*1135C>T | 3'UTR (SNP) | VAF 39/90 reads (43%) | catalogued as rs756377182; called by muse, mutect2, varscan2
- SERPINB7 | c.*394G>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- SPAG16 | c.536+122G>A | Intron (SNP) | VAF 29/74 reads (39%) | catalogued as rs1364694803; called by muse, mutect2, varscan2
- SRD5A3 | c.*622C>T | 3'UTR (SNP) | VAF 10/33 reads (30%) | catalogued as rs951741748; called by muse, mutect2, varscan2
- STRN | c.*4884T>C | 3'UTR (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- TECRL | c.*209A>C | 3'UTR (SNP) | VAF 49/156 reads (31%) | called by muse, mutect2, varscan2
- TENM1 | c.*2280G>A | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- TGFBR2 | c.*1808A>C | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- TLE3 | c.25-75G>A | Intron (SNP) | VAF 46/123 reads (37%) | called by muse, mutect2, varscan2
- TMEM176A | c.666+136C>A | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- TNFRSF11B | c.*105C>A | 3'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- TTC39C | c.985-737C>T | Intron (SNP) | VAF 32/79 reads (41%) | catalogued as rs967257932; called by muse, mutect2, varscan2
- TTN | c.10361-4755A>C | Intron (SNP) | VAF 207/508 reads (41%) | called by muse, mutect2, varscan2
- WBP4 | chr13:41061321 C>T | 5'Flank (SNP) | VAF 98/228 reads (43%) | catalogued as rs1248102901; called by muse, mutect2, varscan2
- WFS1 | c.316-97T>A | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- ZC4H2 | c.54-69A>T | Intron (SNP) | VAF 140/345 reads (41%) | called by muse, mutect2, varscan2
